TCGA case TCGA-B0-4852 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/759238f2-0d37-404e-96f1-c26cae0ba2ea

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Dead; Days to death: 1,121 days (3.1 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 78.2 years (28,552 days); Year of diagnosis: 2004; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 80.5 years (29,412 days); Days to diagnosis: 860 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 860 days (2.4 years); Treatment anatomic sites: Distant Site.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (2 entries)
- Day 860 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 860 days (2.4 years).
- Days to follow up: 1,121 days (3.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Low.
- Calcium: Low.
- Leukocytes: Normal.
- Platelets: Elevated.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B0-4852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-B0-4852-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-B0-4852-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-B0-4852-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B0-4852-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 0.8; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event surgery met: Yes; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,121 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,121 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 860 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B0-4852-01A-01D-1499-01): tumor purity 0.67, ploidy 2.03, whole-genome doublings 0.
